Somatic mutation profile of tumor specimen TCGA-24-1431-01A (aliquot TCGA-24-1431-01A-01D-0472-01) from TCGA case TCGA-24-1431, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 67.8 years (24,758 days).
Specimen TCGA-24-1431-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 84a29fe6-cd5b-408d-87de-0ceffefe67ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1431-10A (Blood Derived Normal), aliquot TCGA-24-1431-10A-01D-0472-01; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/a1bbc432-f01b-43bf-adbd-ef94d7238721

The open-access MAF lists 86 somatic variants for this specimen: 66 protein-altering or splice-affecting, 17 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 56, Silent 17, Nonsense Mutation 5, Splice Site 2, Intron 2, In Frame Del 2, RNA 1, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TG | c.7123G>A p.G2375R | Missense Mutation (SNP) | VAF 33/96 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs137854434, CM063182, COSV99601176; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.574C>T p.Q192* | Nonsense Mutation (SNP) | VAF 65/73 reads (89%) | hotspot (GDC flag); catalogued as rs866380588, COSV52660737, COSV52978302; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ACOT9 | c.838G>T p.V280F | Missense Mutation (SNP) | VAF 15/135 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.439); catalogued as COSV60536942, COSV60538703; called by muse, mutect2, varscan2
- ADAMTSL1 | c.2138G>A p.R713H | Missense Mutation (SNP) | VAF 36/83 reads (43%) | SIFT tolerated (0.31); PolyPhen benign (0); catalogued as rs766340602, COSV65890090; called by muse, mutect2, varscan2
- ANKZF1 | c.1498G>C p.A500P | Missense Mutation (SNP) | VAF 4/22 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.855); catalogued as COSV55478353; called by muse, mutect2, varscan2
- APH1A | c.359-1G>A p.X120_splice | Splice Site (SNP) | VAF 6/98 reads (6%) | catalogued as COSV99354442; called by muse, mutect2
- ARMC2 | c.2276G>A p.G759D | Missense Mutation (SNP) | VAF 4/33 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100933600; called by muse, mutect2, varscan2
- ATP1B1 | c.200C>T p.T67I | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.639); catalogued as COSV63179896; called by muse, mutect2, varscan2
- CA12 | c.1043T>C p.M348T | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV99458421; called by muse, mutect2, varscan2
- CFH | c.2014C>A p.Q672K | Missense Mutation (SNP) | VAF 85/524 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.373); catalogued as COSV66405951, COSV66408598; called by muse, mutect2, varscan2
- CHRD | c.1537G>A p.G513R | Missense Mutation (SNP) | VAF 12/49 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs760580943, COSV52611496; called by muse, mutect2, varscan2
- CIITA | c.2769G>T p.K923N | Missense Mutation (SNP) | VAF 22/61 reads (36%) | SIFT tolerated (0.07); PolyPhen benign (0.283); catalogued as COSV100162242; called by muse, mutect2, varscan2
- CILP2 | c.606C>G p.D202E | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.051); catalogued as COSV52279108; called by muse, mutect2, varscan2
- DOP1B | c.2422T>G p.Y808D | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT tolerated (0.24); PolyPhen benign (0.021); catalogued as COSV101215546; called by muse, mutect2
- DTNBP1 | c.233G>C p.S78T | Missense Mutation (SNP) | VAF 12/190 reads (6%) | SIFT tolerated (0.31); PolyPhen benign (0.041); catalogued as COSV100160917; called by muse, mutect2
- ELOA | c.493C>A p.L165I | Missense Mutation (SNP) | VAF 17/176 reads (10%) | SIFT tolerated (0.41); PolyPhen benign (0.039); catalogued as COSV69311131; called by muse, mutect2, varscan2
- FAT3 | c.3777C>A p.Y1259* | Nonsense Mutation (SNP) | VAF 399/1592 reads (25%) | catalogued as COSV53159383; called by muse, mutect2, varscan2
- GP2 | c.686G>A p.C229Y (on ENST00000381362 / NM_001007240.3; = p.C226Y on NM_001502.4) | Missense Mutation (SNP) | VAF 6/44 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100221544; called by mutect2, varscan2
- HRNR | c.1701G>T p.R567S | Missense Mutation (SNP) | VAF 23/83 reads (28%) | SIFT tolerated (0.77); PolyPhen benign (0.003); catalogued as rs565962724, COSV64257609; called by muse, mutect2, varscan2
- HSD17B2 | c.555C>A p.Y185* | Nonsense Mutation (SNP) | VAF 8/178 reads (4%) | catalogued as COSV99556670; called by muse, mutect2
- HTR1A | c.179C>T p.A60V | Missense Mutation (SNP) | VAF 8/36 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); catalogued as COSV60502427; called by muse, mutect2, varscan2
- IQGAP2 | c.3778G>A p.D1260N | Missense Mutation (SNP) | VAF 62/80 reads (78%) | SIFT tolerated (0.17); PolyPhen benign (0.023); catalogued as COSV57179708; called by muse, mutect2, varscan2
- ITGA5 | c.539C>G p.T180R | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT tolerated (0.06); PolyPhen benign (0.203); catalogued as COSV99516725; called by muse, mutect2, varscan2
- KCNJ11 | c.752T>C p.L251P | Missense Mutation (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100379138; called by muse, mutect2
- LGR4 | c.2822G>T p.R941L | Missense Mutation (SNP) | VAF 190/358 reads (53%) | SIFT tolerated, low confidence (0.09); PolyPhen possibly damaging (0.627); catalogued as COSV58725665; called by muse, varscan2
- LRRTM1 | c.1547C>A p.P516H | Missense Mutation (SNP) | VAF 11/68 reads (16%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.915); catalogued as COSV54443844; called by muse, mutect2
- MINDY4 | c.446T>A p.L149H | Missense Mutation (SNP) | VAF 11/150 reads (7%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.459); catalogued as COSV99518912; called by muse, mutect2
- MKLN1 | c.1805G>T p.G602V | Missense Mutation (SNP) | VAF 17/292 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV100759886; called by muse, mutect2
- MMP13 | c.11G>C p.G4A | Missense Mutation (SNP) | VAF 59/121 reads (49%) | SIFT tolerated (0.59); PolyPhen benign (0); catalogued as COSV99506654; called by muse, mutect2, varscan2
- MUC16 | c.7175G>A p.S2392N | Missense Mutation (SNP) | VAF 8/176 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV101200316; called by muse, mutect2
- NEURL4 | c.1097G>A p.R366H | Missense Mutation (SNP) | VAF 18/26 reads (69%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs781226135, COSV59757908; called by muse, mutect2, varscan2
- OR56A1 | c.10C>A p.P4T | Missense Mutation (SNP) | VAF 387/780 reads (50%) | SIFT tolerated (0.71); PolyPhen benign (0.045); catalogued as COSV57363601; called by muse, mutect2, varscan2
- PAK5 | c.2116C>G p.P706A | Missense Mutation (SNP) | VAF 24/662 reads (4%) | SIFT deleterious (0.02); PolyPhen benign (0.195); catalogued as COSV100781454, COSV99058911; called by muse, mutect2
- PCSK5 | c.3431A>G p.D1144G | Missense Mutation (SNP) | VAF 22/83 reads (27%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as rs1335997562, COSV101377564; called by muse, mutect2, varscan2
- PNISR | c.700G>A p.A234T | Missense Mutation (SNP) | VAF 12/93 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs757675220, COSV65080458; called by muse, mutect2, varscan2
- PRB4 | c.635A>T p.N212I | Missense Mutation (SNP) | VAF 190/822 reads (23%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.449); catalogued as COSV54399552; called by muse, mutect2, varscan2
- PRSS54 | c.41G>A p.R14Q | Missense Mutation (SNP) | VAF 8/25 reads (32%) | SIFT tolerated (0.05); PolyPhen benign (0.159); catalogued as rs1425609799, COSV54690993; called by muse, mutect2, varscan2
- PTCH2 | c.265G>A p.V89M | Missense Mutation (SNP) | VAF 24/117 reads (21%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.753); catalogued as COSV100942167; called by mutect2, varscan2
- PTDSS1 | c.1233C>A p.H411Q | Missense Mutation (SNP) | VAF 20/173 reads (12%) | SIFT tolerated (0.57); PolyPhen benign (0); catalogued as COSV61266085; called by muse, mutect2, varscan2
- PTPRG | c.3378A>C p.E1126D | Missense Mutation (SNP) | VAF 237/487 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.496); catalogued as COSV99875594; called by muse, mutect2, varscan2
- RARS2 | c.1639G>T p.E547* | Nonsense Mutation (SNP) | VAF 9/154 reads (6%) | catalogued as COSV101057355; called by muse, mutect2
- RBAK | c.26C>T p.S9L | Missense Mutation (SNP) | VAF 133/416 reads (32%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.987); catalogued as COSV100806699; called by muse, mutect2, varscan2
- RBM28 | c.1974G>C p.Q658H | Missense Mutation (SNP) | VAF 26/581 reads (4%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV99775774; called by muse, mutect2
- RBPJL | c.1474G>A p.A492T | Missense Mutation (SNP) | VAF 60/223 reads (27%) | SIFT tolerated (0.31); PolyPhen benign (0.017); catalogued as COSV59215358; called by muse, mutect2, varscan2
- RTN2 | c.1129G>A p.V377M | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs146778767; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- RUBCN | c.1116G>T p.Q372H | Missense Mutation (SNP) | VAF 10/102 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV99584377; called by muse, mutect2
- SFTPA2 | c.275G>T p.G92V | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.896); catalogued as COSV100958802; called by muse, mutect2
- SH3PXD2A | c.2417C>T p.T806M (on ENST00000369774 / NM_001365079.1; = p.T778M on NM_014631.2) | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1167375308, COSV60115727; called by muse, mutect2, varscan2
- STEAP2 | c.436T>C p.F146L | Missense Mutation (SNP) | VAF 56/351 reads (16%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.996); catalogued as COSV55293113; called by muse, mutect2, varscan2
- TANC2 | c.4016G>A p.R1339K | Missense Mutation (SNP) | VAF 31/63 reads (49%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as COSV67339870; called by muse, mutect2, varscan2
- TLN2 | c.7021G>A p.D2341N | Missense Mutation (SNP) | VAF 62/270 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs760063033, COSV60894175; called by muse, mutect2, varscan2
- TMEM214 | c.1568C>A p.P523H | Missense Mutation (SNP) | VAF 9/180 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV99476392; called by muse, mutect2
- TNFRSF11B | c.883C>A p.L295I | Missense Mutation (SNP) | VAF 5/74 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99816751; called by muse, mutect2
- TNS2 | c.4108G>A p.A1370T (on ENST00000314250 / NM_170754.4; = p.A1380T on NM_015319.2) | Missense Mutation (SNP) | VAF 10/54 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100036782; called by muse, mutect2, varscan2
- TXNRD2 | c.582C>G p.Y194* | Nonsense Mutation (SNP) | VAF 6/46 reads (13%) | catalogued as rs1334681677, COSV57635169; called by mutect2, varscan2
- UGP2 | c.175C>T p.R59W | Missense Mutation (SNP) | VAF 198/679 reads (29%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.67); catalogued as rs776077450, COSV61427388; called by muse, mutect2, varscan2
- USP34 | c.8848A>G p.R2950G | Missense Mutation (SNP) | VAF 18/66 reads (27%) | SIFT deleterious (0.04); PolyPhen benign (0.023); catalogued as COSV68404980; called by muse, mutect2, varscan2
- ZFAND5 | c.583G>T p.A195S | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV99428543; called by muse, mutect2
- ZNF416 | c.781C>A p.Q261K | Missense Mutation (SNP) | VAF 24/316 reads (8%) | SIFT tolerated (0.08); PolyPhen benign (0.023); catalogued as COSV99543865; called by muse, mutect2
- C1GALT1C1L | c.427C>A p.P143T | Missense Mutation (SNP) | VAF 42/1080 reads (4%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.993); called by muse, mutect2
- KRT77 | c.169_189del p.G57_N63del | In Frame Del (DEL) | VAF 9/33 reads (27%) | called by mutect2, pindel
- PFKM | c.2093-18_2118del p.X698_splice | Splice Site (DEL) | VAF 17/63 reads (27%) | called by mutect2, pindel
- PPP2R1A | c.1495del p.M499* | Frame Shift Del (DEL) | VAF 40/227 reads (18%) | called by mutect2, pindel, varscan2
- STXBP4 | c.1412G>A p.G471E | Missense Mutation (SNP) | VAF 6/149 reads (4%) | SIFT tolerated (0.07); PolyPhen benign (0.062); called by muse, mutect2
- TREML2 | c.872_874del p.K291del | In Frame Del (DEL) | VAF 14/58 reads (24%) | called by pindel, varscan2
- TUBB4A | c.1070C>T p.P357L | Missense Mutation (SNP) | VAF 19/422 reads (5%) | SIFT deleterious, low confidence (0.02); PolyPhen probably damaging (0.917); called by muse, mutect2
- BPI | c.1188C>T p.S396= (on ENST00000262865; = p.S392= on NM_001725.3) | Silent (SNP) | VAF 11/64 reads (17%) | catalogued as COSV53407742; called by muse, mutect2, varscan2
- CCDC171 | c.2766T>C p.C922= | Silent (SNP) | VAF 8/103 reads (8%) | catalogued as COSV99901150; called by muse, mutect2
- CD83 | c.213G>A p.Q71= | Silent (SNP) | VAF 14/150 reads (9%) | catalogued as rs905993967, COSV100997827, COSV64788648; called by muse, mutect2
- DACT3 | c.1689C>A p.A563= | Silent (SNP) | VAF 7/41 reads (17%) | catalogued as COSV56261069; called by muse, mutect2, varscan2
- ECI2 | c.756C>A p.T252= (on ENST00000380118 / NM_206836.3; = p.T222= on NM_006117.2) | Silent (SNP) | VAF 28/408 reads (7%) | catalogued as COSV100326580; called by muse, mutect2
- ECM1 | c.588A>G p.P196= | Silent (SNP) | VAF 138/603 reads (23%) | catalogued as rs746209582, COSV60874575; called by muse, mutect2, varscan2
- EYA1 | c.876T>C p.S292= | Silent (SNP) | VAF 46/1812 reads (3%) | catalogued as COSV100379698; called by muse, mutect2
- IQGAP2 | c.2904C>T p.V968= | Silent (SNP) | VAF 8/122 reads (7%) | catalogued as rs1008376066, COSV99167560, COSV99167909; called by muse, mutect2
- KMT2C | c.12315T>G p.L4105= | Silent (SNP) | VAF 72/302 reads (24%) | catalogued as COSV100073484; called by muse, mutect2, varscan2
- MADD | c.4218G>T p.G1406= | Silent (SNP) | VAF 42/181 reads (23%) | catalogued as COSV100211627; called by muse, mutect2, varscan2
- MTR | c.1702T>C p.L568= | Silent (SNP) | VAF 46/241 reads (19%) | catalogued as COSV63966094; called by muse, mutect2, varscan2
- SMG5 | c.2154A>G p.E718= | Silent (SNP) | VAF 11/37 reads (30%) | catalogued as COSV62437194; called by muse, mutect2, varscan2
- TRRAP | c.7011G>A p.V2337= (on ENST00000359863 / NM_001244580.1; = p.V2319= on NM_003496.3) | Silent (SNP) | VAF 22/134 reads (16%) | catalogued as COSV100722627; called by mutect2, varscan2
- VPS13A | c.4839C>A p.V1613= | Silent (SNP) | VAF 34/114 reads (30%) | catalogued as COSV100653046; called by muse, mutect2, varscan2
- WSCD2 | c.426C>A p.A142= | Silent (SNP) | VAF 12/176 reads (7%) | catalogued as COSV99774806; called by muse, mutect2
- ZNF121 | c.288C>G p.A96= | Silent (SNP) | VAF 171/177 reads (97%) | catalogued as COSV100248072, COSV57552280; called by muse, mutect2, varscan2
- ZNF213 | c.754C>T p.L252= | Silent (SNP) | VAF 104/134 reads (78%) | catalogued as COSV67728197; called by muse, mutect2, varscan2
- AL163540.1 | n.327G>T | RNA (SNP) | VAF 385/777 reads (50%) | called by muse, mutect2, varscan2
- MGAM | c.4618+279del | Intron (DEL) | VAF 85/240 reads (35%) | called by mutect2, pindel, varscan2
- SH3TC1 | c.172+208G>A | Intron (SNP) | VAF 4/12 reads (33%) | catalogued as rs1306231164, COSV99795031; called by muse, mutect2
